Somatic mutation profile of tumor specimen TCGA-AJ-A2QO-01A (aliquot TCGA-AJ-A2QO-01A-11D-A18P-09) from TCGA case TCGA-AJ-A2QO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 85.5 years (31,222 days).
Specimen TCGA-AJ-A2QO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 655796a9-7172-4883-a2d1-b075c9a974a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A2QO-10A (Blood Derived Normal), aliquot TCGA-AJ-A2QO-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91ac5bd4-e381-47fe-8529-fe2b6d6b658e

The open-access MAF lists 1,343 somatic variants for this specimen: 1,025 protein-altering or splice-affecting, 277 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 639, Silent 277, Frame Shift Del 271, Frame Shift Ins 52, Nonsense Mutation 33, Intron 17, Splice Site 16, Splice Region 8, RNA 8, In Frame Del 6, 3'UTR 5, 5'Flank 5.

Variants (750 of 1,343; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 43/115 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CCND1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119846, COSV57120106, COSV57120715; called by muse, mutect2, varscan2
- COL5A1 | c.5473C>T p.Q1825* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs1057518004, COSV100879641; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- DSG2 | c.2533del p.I845* | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs1375081885; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- GRM1 | c.26del p.F9Sfs*119 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MED12 | c.1849A>G p.T617A | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs765417606, COSV100376703; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 60/137 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67960075, COSV67960449, COSV67960680; called by muse, mutect2, varscan2
- NOTCH3 | c.5926dup p.L1976Pfs*11 | Frame Shift Ins (INS) | VAF 12/33 reads (36%) | catalogued as rs1555725170; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NSD1 | c.6349C>T p.R2117* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as rs587784190, CM056664, COSV100728579; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel
- PTEN | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 43/97 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876660507, CM110142, COSV64288690, COSV64296946; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC6A1 | c.1328del p.X443_splice | Splice Site (DEL) | VAF 19/47 reads (40%) | catalogued as rs1199489242; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- VWF | c.2435del p.P812Rfs*31 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs62643632, CD920917, CM074633, COSV54614968; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- WDR19 | c.641dup p.L214Ffs*5 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | catalogued as rs587777348; ClinVar: pathogenic; called by mutect2, varscan2
- A1BG | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.531); catalogued as rs1258915234, COSV54049815; called by muse, mutect2, varscan2
- AAAS | c.771del p.R258Gfs*33 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs1184877278, CD067140; called by mutect2, pindel, varscan2
- AAAS | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs767269111, COSV99266856; called by muse, mutect2
- AAMP | c.1160C>A p.A387D | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV99946221; called by muse, mutect2, varscan2
- ABCA1 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101036649; called by muse, mutect2, varscan2
- ABCA13 | c.10253G>A p.R3418H | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs764681827, COSV71287219, COSV71287487; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCC5 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs1031185065, COSV99656569; called by muse, mutect2
- ABI3 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.796); catalogued as rs868437723, COSV56800350, COSV99865340; called by muse, mutect2, varscan2
- AC131160.1 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100226125; called by muse, mutect2, varscan2
- ACAD10 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV100563912; called by muse, mutect2, varscan2
- ACAD9 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs780122392, COSV100459003; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | catalogued as rs757016425; called by mutect2, varscan2
- ACTN1 | c.428-2A>G p.X143_splice | Splice Site (SNP) | VAF 38/80 reads (48%) | catalogued as COSV99517440; called by muse, mutect2, varscan2
- ACTN1 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV99517442; called by muse, mutect2, varscan2
- ACTN4 | c.2619del p.D874Tfs*44 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | catalogued as rs869292397; called by mutect2, pindel, varscan2
- ACTRT2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs770687267, COSV65759501; called by muse, mutect2, varscan2
- ACVR1B | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1408456448, COSV99231309; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 30/62 reads (48%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM22 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs369078128; called by muse, mutect2, varscan2
- ADAMTS2 | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs752222373, COSV99281298; called by muse, mutect2, varscan2
- ADAMTS7 | c.3999G>T p.W1333C | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.338); catalogued as COSV101183039; called by muse, mutect2
- ADCY4 | c.2827del p.Q943Rfs*45 | Frame Shift Del (DEL) | VAF 13/145 reads (9%) | catalogued as COSV100156859; called by mutect2, pindel
- ADCY6 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1315744797, COSV100326453; called by muse, mutect2, varscan2
- ADCY7 | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs967639581, COSV54268562; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRE3 | c.1664C>T p.T555I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as COSV99505931; called by muse, mutect2, varscan2
- ADGRG1 | c.1683-1G>T p.X561_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as COSV101113373; called by muse, mutect2
- ADGRV1 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV101315603; called by muse, mutect2, varscan2
- ADNP2 | c.3100G>A p.E1034K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs937743050, COSV100080611; called by muse, mutect2, varscan2
- AFDN | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770846848, COSV60042184, COSV60049837; called by muse, mutect2, varscan2
- AJAP1 | c.1135del p.E379Sfs*74 (on ENST00000378190 / NM_001042478.2; = p.E379Sfs*58 on NM_018836.4) | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as COSV100981542, COSV65451503; called by mutect2, pindel, varscan2
- AJUBA | c.1555C>T p.L519F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.32); catalogued as COSV99400862; called by muse, mutect2, varscan2
- AKT2 | c.713T>C p.F238S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100251462; called by muse, mutect2
- ALAS2 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759169409, COSV100238087, COSV58189524; called by muse, mutect2, varscan2
- ALDH3B1 | c.1334C>A p.P445Q | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99141730; called by muse, mutect2
- ALG13 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1060500008, COSV52637744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPI | c.1252T>C p.Y418H | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as COSV99785740; called by muse, mutect2, varscan2
- ALPK3 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99360408; called by muse, mutect2, varscan2
- ALS2CL | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.747); catalogued as COSV100014839; called by muse, mutect2, varscan2
- AMPH | c.505-1G>T p.X169_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100341259; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99782397; called by muse, mutect2, varscan2
- ANKLE1 | c.1792G>A p.A598T (on ENST00000394458; = p.A544T on NM_152363.6) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs547043530, COSV101081978; called by muse, mutect2, varscan2
- ANKMY1 | c.1508C>A p.P503Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as COSV99801552; called by muse, mutect2, varscan2
- ANKRD11 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778367008, COSV56373908; called by muse, mutect2, varscan2
- AP1M1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV52224682; called by muse, mutect2
- APBA1 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs766705353, COSV99595628; called by muse, mutect2, varscan2
- APOB | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as rs201595604, COSV99264268; called by muse, mutect2, varscan2
- APOBEC1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs899513257, COSV99981023; called by muse, mutect2, varscan2
- AQP1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs748039521, COSV61266109; called by muse, mutect2, varscan2
- ARAP3 | c.3150G>A p.M1050I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1192206607, COSV99499423; called by muse, mutect2, varscan2
- ARHGAP20 | c.3506C>T p.A1169V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs200417489; called by muse, mutect2, varscan2
- ARHGEF10 | c.2447C>T p.P816L (on ENST00000398564; = p.P791L on NM_014629.4) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV50668807; called by muse, mutect2, varscan2
- ARHGEF10L | c.3320T>C p.V1107A | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV99392223; called by muse, mutect2, varscan2
- ARHGEF17 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV99735043; called by muse, mutect2, varscan2
- ARHGEF25 | c.1015C>A p.L339M | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99677642; called by muse, mutect2, varscan2
- ARID1A | c.1636del p.Q546Rfs*73 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as COSV61383992, COSV61391080; called by mutect2, pindel, varscan2
- ARID1A | c.4582C>T p.R1528* | Nonsense Mutation (SNP) | VAF 30/71 reads (42%) | catalogued as COSV100251965, COSV61372105; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs758608743; called by mutect2, varscan2
- ARNT | c.2153G>T p.R718L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99648581; called by muse, mutect2, varscan2
- ARRB1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.272); catalogued as rs373743647, COSV100758216; called by muse, mutect2, varscan2
- ARSD | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV99472028; called by muse, mutect2, varscan2
- ARX | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100984041; called by muse, mutect2
- ASAP3 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374050468; called by muse, mutect2, varscan2
- ASB4 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV100367112; called by muse, mutect2, varscan2
- ATG5 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as COSV58347620; called by muse, mutect2, varscan2
- ATP2B3 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99683443; called by muse, mutect2, varscan2
- ATP2C2 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781396467, COSV52297755; called by muse, mutect2
- ATP6V1B2 | c.160A>G p.N54D | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as COSV99369297; called by muse, mutect2
- ATP7B | c.3555C>T p.D1185= | Splice Region (SNP) | VAF 14/67 reads (21%) | catalogued as rs756751716, COSV54436155, COSV54438842; called by muse, mutect2, varscan2
- ATR | c.6089C>T p.A2030V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs755650081, COSV63383698, COSV63384373; called by muse, mutect2
- ATXN7 | c.2543A>G p.N848S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371435328, COSV55749868; called by mutect2, varscan2
- BCAR1 | c.814A>G p.M272V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.166); catalogued as COSV99366183; called by muse, mutect2, varscan2
- BCL11B | c.1379G>A p.C460Y (on ENST00000357195 / NM_001282237.2; = p.C389Y on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100595263; called by muse, mutect2, varscan2
- BCL9L | c.2716C>A p.P906T | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV99418848; called by muse, mutect2, varscan2
- BCL9L | c.1125del p.G376Afs*87 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as COSV52682570; called by mutect2, varscan2
- BIVM-ERCC5 | c.4894C>T p.R1632C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.1); catalogued as rs768302699, COSV100863655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMS1 | c.2774G>A p.R925H | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs2419106, COSV100996579; called by muse, mutect2, varscan2
- BOC | c.2300T>C p.M767T | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV99848322; called by muse, mutect2
- BRMS1L | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV99396556; called by muse, mutect2, varscan2
- BRWD3 | c.3578G>A p.R1193Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs754078647, COSV100955779; called by muse, mutect2, varscan2
- BSX | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.288); catalogued as COSV100545153; called by muse, mutect2, varscan2
- BTBD9 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100021217; called by muse, mutect2, varscan2
- BTN3A3 | c.1553T>A p.V518E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV55073616, COSV99764791; called by muse, mutect2, varscan2
- C19orf57 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.225); catalogued as rs1460634148, COSV100694646; called by muse, mutect2, varscan2
- C1QL1 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99492699; called by muse, mutect2, varscan2
- C2CD6 | c.1855del p.I619Lfs*19 | Frame Shift Del (DEL) | VAF 30/62 reads (48%) | catalogued as rs752496395; called by mutect2, varscan2
- C3 | c.3023C>T p.S1008L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as rs746172422, CM160563, COSV55570145; called by muse, mutect2, varscan2
- C4BPB | c.10dup p.W4Lfs*29 | Frame Shift Ins (INS) | VAF 46/114 reads (40%) | catalogued as rs1558074374; called by mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- C6orf15 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs139294392; called by muse, mutect2, varscan2
- C8orf34 | c.1292T>C p.L431P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.533); catalogued as COSV100297742, COSV57404667; called by muse, mutect2
- CABLES2 | c.1105A>G p.M369V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1569014512, COSV99653021; called by muse, mutect2, varscan2
- CALCOCO2 | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV99363679, COSV99363983; called by muse, mutect2, varscan2
- CAMSAP1 | c.1161dup p.V388Rfs*19 | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | catalogued as rs750552002; called by mutect2, pindel, varscan2
- CATSPER1 | c.703C>A p.H235N | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV100375708; called by muse, mutect2, varscan2
- CATSPERG | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.856); catalogued as rs775514341, COSV99286197; called by muse, mutect2, varscan2
- CAV2 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1171200240, COSV56063946, COSV99760747; called by muse, mutect2, varscan2
- CC2D2A | c.2921A>G p.Q974R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV101052686; called by muse, mutect2, varscan2
- CCDC130 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.105); catalogued as rs372266888; called by muse, mutect2, varscan2
- CCDC14 | c.1145del p.N382Mfs*2 (on ENST00000488653; = p.N334Mfs*2 on NM_022757.5) | Frame Shift Del (DEL) | VAF 37/135 reads (27%) | catalogued as rs1559796959; called by mutect2, pindel, varscan2
- CCDC148 | c.1260dup p.Y421Ifs*29 | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | catalogued as rs761447262; called by mutect2, varscan2
- CCDC158 | c.610dup p.I204Nfs*3 | Frame Shift Ins (INS) | VAF 18/39 reads (46%) | catalogued as rs1248476350; called by mutect2, varscan2
- CCDC180 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100826500; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC33 | c.673G>T p.G225W | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100350809; called by muse, mutect2, varscan2
- CCDC71 | c.1354C>A p.L452M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100422306; called by muse, mutect2, varscan2
- CCDC87 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV100039824; called by muse, mutect2, varscan2
- CCDC88C | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs780818616, COSV101105298; called by muse, mutect2, varscan2
- CCN4 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs201917230, COSV51531258; called by muse, mutect2, varscan2
- CCNE2 | c.124del p.R42Efs*38 | Frame Shift Del (DEL) | VAF 28/121 reads (23%) | catalogued as rs1563685429; called by mutect2, pindel, varscan2
- CCT6A | c.820del p.I274* | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs1482449902; called by mutect2, varscan2
- CD101 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99869265; called by muse, mutect2, varscan2
- CD81 | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99719152; called by muse, mutect2, varscan2
- CDC42BPB | c.4374G>T p.Q1458H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV100775284; called by mutect2, varscan2
- CDH10 | c.2054del p.K685Sfs*34 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | catalogued as rs1561116064; called by pindel, varscan2
- CDH23 | c.7252G>T p.G2418C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99819470; called by muse, mutect2, varscan2
- CDH23 | c.9256A>C p.M3086L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV99819473; called by muse, mutect2, varscan2
- CDH9 | c.671T>C p.M224T | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV99142201; called by muse, mutect2, varscan2
- CDK19 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100098168; called by muse, mutect2, varscan2
- CDK2AP2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV100039348; called by muse, mutect2
- CDKL5 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs199897804, COSV66111013, COSV66114262; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- CDKN2AIP | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100187557, COSV56628204; called by muse, mutect2, varscan2
- CEACAM5 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV99703781; called by muse, mutect2, varscan2
- CELSR2 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1312965091, COSV54768941; called by muse, mutect2, varscan2
- CEMIP2 | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs374929106; called by muse, mutect2, varscan2
- CENPF | c.3636A>T p.Q1212H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as COSV100871567, COSV65274976; called by muse, mutect2, varscan2
- CEP128 | c.2098C>G p.L700V | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.217); catalogued as COSV55370856, COSV99823940; called by muse, mutect2
- CEP20 | c.53del p.K18Rfs*4 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | catalogued as rs746479678; called by mutect2, pindel, varscan2
- CEP350 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100854379; called by muse, mutect2, varscan2
- CERK | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs549806434, COSV53449950; called by muse, mutect2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP43 | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99530469; called by muse, mutect2, varscan2
- CFAP77 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199991031, COSV58013393; called by muse, mutect2, varscan2
- CGNL1 | c.2990C>T p.T997M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs370555915; called by muse, mutect2, varscan2
- CHCHD4 | c.218C>T p.S73F (on ENST00000396914 / NM_001098502.2; = p.S86F on NM_144636.3) | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99853915; called by muse, mutect2, varscan2
- CHD1 | c.4930C>T p.R1644W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs146540815; called by muse, mutect2, varscan2
- CHD2 | c.5345C>A p.P1782H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV101244857; called by muse, mutect2, varscan2
- CHD7 | c.5725C>A p.L1909M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV101418063; called by muse, mutect2, varscan2
- CHD9 | c.5683C>T p.R1895W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773225940, COSV99528836; called by muse, mutect2, varscan2
- CHERP | c.1362del p.W455Gfs*200 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | catalogued as rs770045437; called by mutect2, pindel
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 24/48 reads (50%) | catalogued as rs751548647; called by mutect2, varscan2
- CIITA | c.1550C>A p.P517Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.835); catalogued as rs765687423, COSV100161531, COSV60858970; called by muse, mutect2, varscan2
- CIRBP | c.350-1G>A p.X117_splice | Splice Site (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100309727; called by mutect2, varscan2
- CITED2 | c.251del p.P84Rfs*63 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs748689446; called by mutect2, pindel, varscan2
- CLASP1 | c.3692del p.G1231Vfs*4 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | catalogued as rs749719822, COSV99752279; called by mutect2, pindel, varscan2
- CLCN7 | c.1427G>T p.S476I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV99246967; called by muse, mutect2, varscan2
- CLEC9A | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100872759; called by muse, mutect2
- CLVS2 | c.320del p.G107Afs*13 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as COSV51568194; called by mutect2, pindel, varscan2
- CNGA3 | c.1625G>T p.S542I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs1405438176, COSV99736267; called by muse, mutect2, varscan2
- CNKSR1 | c.797T>C p.M266T (on ENST00000374253 / NM_001297647.2; = p.M259T on NM_006314.3) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100836703; called by muse, mutect2, varscan2
- CNNM4 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV65662160; called by muse, mutect2, varscan2
- CNTRL | c.3358C>T p.R1120* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as rs1564271317, COSV99441472; called by muse, mutect2, varscan2
- CNTROB | c.2699del p.G900Efs*34 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | catalogued as rs35508310, COSV66608279; called by mutect2, pindel, varscan2
- COL6A3 | c.5311del p.V1771Sfs*8 | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | catalogued as COSV55082747; called by mutect2, varscan2
- COL6A3 | c.4690C>T p.R1564C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs200825417, COSV55101667; called by muse, mutect2, varscan2
- COL7A1 | c.7951C>T p.R2651C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs142103925; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as rs143616972; called by muse, mutect2, varscan2
- COX6B2 | c.30dup p.K11Qfs*21 | Frame Shift Ins (INS) | VAF 17/73 reads (23%) | catalogued as rs1569026302, COSV100427803; called by mutect2, pindel, varscan2
- COX7A1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs747380164, COSV99497037; called by muse, varscan2
- CPA4 | c.891del p.K297Nfs*18 | Frame Shift Del (DEL) | VAF 22/41 reads (54%) | catalogued as rs755208608; called by mutect2, pindel, varscan2
- CPEB3 | c.188del p.P63Rfs*19 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs751359395; called by mutect2, pindel, varscan2
- CPLX2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as COSV100853015; called by muse, mutect2, varscan2
- CPT1B | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV100376538; called by muse, mutect2, varscan2
- CRB1 | c.1931A>G p.Q644R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.182); catalogued as COSV66332988; called by muse, mutect2, varscan2
- CSE1L | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1360257614, COSV53701609; called by muse, mutect2, varscan2
- CSF1R | c.1055C>G p.A352G | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53832454, COSV99641144; called by muse, mutect2
- CSMD1 | c.10570G>A p.A3524T (on ENST00000520002; = p.A3523T on NM_033225.6) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs530793092, COSV100145076; called by muse, mutect2, varscan2
- CSNK2A1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs1057518092, COSV53933710, COSV99424810; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic / not provided; called by muse, varscan2
- CTNNA2 | c.2828C>A p.A943D (on ENST00000402739 / NM_001282597.3; = p.A895D on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100559633; called by muse, mutect2
- CTNND1 | c.2201T>C p.L734P (on ENST00000399050 / NM_001085458.2; = p.L728P on NM_001331.3) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649909; called by muse, mutect2, varscan2
- CUBN | c.9995G>A p.C3332Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100912218; called by muse, mutect2, varscan2
- CXCL6 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as COSV56903118, COSV56903547; called by muse, mutect2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP11B1 | c.96del p.R33Gfs*18 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs768007725, CD930942; called by mutect2, pindel, varscan2
- CYP4V2 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as CM074770, COSV101114778; called by muse, mutect2, varscan2
- CYREN | c.389del p.G130Vfs*19 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | catalogued as rs753942205; called by mutect2, pindel, varscan2
- CYTIP | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as rs371636217; called by muse, mutect2, varscan2
- DAB2IP | c.1681C>A p.L561M (on ENST00000408936; = p.L533M on NM_032552.3) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99404922; called by muse, mutect2, varscan2
- DCHS1 | c.3523A>G p.S1175G | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs747027839, COSV100201662; called by muse, mutect2, varscan2
- DDB2 | c.703-2A>G p.X235_splice | Splice Site (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99921515; called by muse, mutect2, varscan2
- DDIAS | c.2156C>T p.S719L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100231068; called by muse, mutect2, varscan2
- DEF6 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1367992165, COSV100359202; called by muse, mutect2, varscan2
- DENND1C | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780186122, COSV100375156, COSV100375200; called by mutect2, varscan2
- DGKZ | c.3110dup p.E1038Rfs*4 (on ENST00000454345 / NM_001105540.2; = p.E850Rfs*4 on NM_003646.4) | Frame Shift Ins (INS) | VAF 24/52 reads (46%) | catalogued as rs3832759; called by mutect2, varscan2
- DHRS2 | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51631298; called by muse, mutect2, varscan2
- DHX30 | c.1396C>T p.R466C (on ENST00000445061 / NM_138615.3; = p.R427C on NM_014966.3) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53138256; called by muse, mutect2, varscan2
- DHX34 | c.1868A>C p.Q623P | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.366); catalogued as COSV100169337; called by muse, mutect2, varscan2
- DIO3 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV63773885; called by muse, mutect2, varscan2
- DIP2C | c.971T>A p.L324Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99790538; called by muse, mutect2, varscan2
- DLL4 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99989672; called by muse, mutect2, varscan2
- DMBT1 | c.3650C>T p.A1217V (on ENST00000338354 / NM_001377530.1; = p.A718V on NM_004406.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100352421; called by mutect2, varscan2
- DMBX1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100760694; called by muse, mutect2, varscan2
- DNAH12 | c.1243+1G>A p.X415_splice | Splice Site (SNP) | VAF 26/75 reads (35%) | catalogued as COSV100244397; called by muse, mutect2, varscan2
- DNAH7 | c.10529A>G p.E3510G | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV100414280; called by muse, mutect2, varscan2
- DNAH7 | c.1037dup p.Q347Afs*6 | Frame Shift Ins (INS) | VAF 8/17 reads (47%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAJC13 | c.3051G>A p.W1017* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99606826; called by muse, mutect2, varscan2
- DNAJC8 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as rs764154355, COSV55283694; called by muse, mutect2, varscan2
- DNTTIP1 | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99708543; called by muse, mutect2, varscan2
- DOC2A | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374821872; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 44/105 reads (42%) | catalogued as rs782552436; called by pindel, varscan2
- DOCK4 | c.4382G>A p.R1461H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs553536468, COSV70242708; called by muse, mutect2, varscan2
- DOCK5 | c.3625A>G p.T1209A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs570494287, COSV99376335; called by muse, mutect2, varscan2
- DPP6 | c.550del p.I184Lfs*4 (on ENST00000377770 / NM_001364500.2; = p.I122Lfs*4 on NM_001936.5) | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs773847741; called by mutect2, pindel, varscan2
- DPY19L4 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV101363147; called by muse, mutect2, varscan2
- DUSP22 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs147959810; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs1409099723, COSV55776265; called by mutect2, pindel, varscan2
- ECE1 | c.1981G>T p.G661W | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99941502; called by muse, mutect2, varscan2
- EDC4 | c.2218C>A p.L740M | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100197513, COSV59302282; called by muse, mutect2, varscan2
- EDEM3 | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545004; called by muse, mutect2, varscan2
- EFEMP2 | c.1220del p.G407Afs*14 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | catalogued as COSV100337415; called by mutect2, pindel
- EFHC2 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs373352491, COSV101375449; called by muse, mutect2, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | catalogued as rs745309220; called by mutect2, pindel
- EIF2AK4 | c.866A>G p.D289G | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as COSV99774264; called by muse, mutect2, varscan2
- EIF2B1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.122); catalogued as COSV99967521; called by muse, mutect2, varscan2
- EIF2B3 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100838914; called by muse, mutect2, varscan2
- EIF3B | c.1897G>A p.G633S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs766601514, COSV62802730; called by muse, mutect2
- EIF4G1 | c.4249G>A p.V1417I (on ENST00000346169 / NM_198241.3; = p.V1222I on NM_004953.5) | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs758267267, COSV100071570; called by muse, mutect2, varscan2
- ELAPOR2 | c.2263G>A p.A755T (on ENST00000450689 / NM_001142749.3; = p.A588T on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV51892309; called by mutect2, varscan2
- ELF2 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV99642681; called by muse, mutect2, varscan2
- ELK1 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99901924; called by muse, mutect2
- ENTPD4 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs759155655, COSV100652546; called by muse, mutect2
- ENTPD6 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1443211025, COSV100737003; called by muse, mutect2, varscan2
- EPPK1 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs373768611; called by muse, mutect2
- ERF | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370521331; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | catalogued as rs775950025; called by mutect2, varscan2
- EVC | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1252737744, COSV99381319; called by muse, mutect2, varscan2
- EVC2 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.526); catalogued as rs369357769; called by muse, varscan2
- EXOC3 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100155176; called by muse, mutect2, varscan2
- EZH1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1287970047, COSV101331348; called by muse, mutect2, varscan2
- FAM110B | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs767303162, COSV64064594; called by muse, mutect2, varscan2
- FAM118A | c.1035dup p.R346Tfs*7 | Frame Shift Ins (INS) | VAF 26/68 reads (38%) | catalogued as rs1356118949; called by mutect2, varscan2
- FAM126B | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs763620315, COSV99627495; called by muse, mutect2, varscan2
- FAM47A | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.659); catalogued as COSV60500448; called by muse, mutect2, varscan2
- FAM71B | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100261932; called by muse, mutect2, varscan2
- FANCE | c.1565T>C p.F522S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100003231; called by muse, mutect2, varscan2
- FANK1 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as rs766618380, COSV100903096; called by muse, mutect2, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as rs757443519; called by mutect2, varscan2
- FBN3 | c.4687G>T p.D1563Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99560215; called by muse, mutect2, varscan2
- FBXL13 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs150674888; called by muse, varscan2
- FBXL19 | c.614del p.P205Rfs*26 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as rs745385709; called by mutect2, varscan2
- FBXO24 | c.1351G>A p.A451T (on ENST00000241071 / NM_033506.3; = p.A489T on NM_012172.5) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs1157674026, COSV99575080; called by muse, mutect2, varscan2
- FCSK | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs865898085, COSV99850607; called by muse, mutect2
- FEZF2 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51863328; called by muse, mutect2
- FHDC1 | c.1199A>G p.Q400R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99471100; called by muse, mutect2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | catalogued as rs777980924; called by mutect2, pindel
- FLII | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100493528; called by muse, mutect2, varscan2
- FLNA | c.4633G>A p.A1545T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100774391; called by muse, mutect2, varscan2
- FLNC | c.3703G>A p.V1235M | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1208885010, COSV57955063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLYWCH1 | c.523G>A p.A175T (on ENST00000253928 / NM_001308068.2; = p.A174T on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs780307376, COSV99558652; called by mutect2, varscan2
- FOXD4 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100070703; called by muse, mutect2, varscan2
- FOXD4 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1195550978, COSV100070705; called by muse, mutect2
- FRMPD3 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1427432277, COSV99345741, COSV99345833; called by muse, mutect2, varscan2
- FRMPD3 | c.4946C>T p.A1649V | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.149); catalogued as rs779911678, COSV99345838; called by muse, mutect2, varscan2
- FRY | c.4606A>G p.S1536G | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100968896; called by muse, mutect2, varscan2
- FXYD5 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs750600377, COSV99544749; called by muse, mutect2, varscan2
- FYN | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV99991301; called by muse, mutect2, varscan2
- FZD7 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.849); catalogued as rs1334110194, COSV99636949; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- G3BP1 | c.958C>A p.R320S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV100663908; called by muse, mutect2, varscan2
- GABRG3 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.817); catalogued as COSV100405697, COSV100409591; called by muse, mutect2, varscan2
- GAS2L1 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99329431; called by muse, mutect2, varscan2
- GBP2 | c.905T>C p.I302T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100975357; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | catalogued as rs548474277; called by mutect2, varscan2
- GCN1 | c.7678C>T p.Q2560* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100324775; called by muse, mutect2
- GCNT3 | c.251C>G p.A84G | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV101251746; called by muse, mutect2, varscan2
- GDI1 | c.403T>C p.F135L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV99340944; called by muse, mutect2, varscan2
- GH2 | c.641G>C p.S214T | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); catalogued as COSV100236883; called by muse, mutect2
- GIGYF2 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs575986326, COSV101004110; called by muse, mutect2, varscan2
- GLA | c.26A>T p.H9L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as CD993482, COSV99516233; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLRA2 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99490472; called by muse, mutect2, varscan2
- GMIP | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138311100; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as rs763679060; called by mutect2, varscan2
- GOLGA2 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746053247, COSV101363082; called by muse, mutect2, varscan2
- GOLGB1 | c.77T>C p.M26T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs753720141, COSV100510439; called by muse, mutect2, varscan2
- GOT1L1 | c.1143C>A p.S381R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100294353; called by muse, mutect2, varscan2
- GPC6 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV100988180; called by muse, mutect2, varscan2
- GPC6 | c.908_909insT p.E303Dfs*7 | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | catalogued as COSV100988181; called by mutect2, pindel, varscan2
- GPHN | c.263C>G p.T88R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100015617; called by muse, mutect2, varscan2
- GPR132 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.091); catalogued as rs750583256, COSV100317464; called by muse, varscan2
- GPR171 | c.269C>A p.T90K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99851977; called by muse, mutect2, varscan2
- GPR180 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV100979009; called by muse, mutect2
- GPR20 | c.893G>A p.C298Y | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.634); catalogued as COSV100897281; called by muse, mutect2, varscan2
- GPSM3 | c.396del p.Q133Kfs*8 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs752813848; called by mutect2, pindel, varscan2
- GRIK1 | c.26A>G p.Q9R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs747041440, COSV100516107; called by muse, mutect2, varscan2
- GRIK5 | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.975); catalogued as COSV99490205; called by muse, mutect2, varscan2
- GRPR | c.1048A>C p.S350R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV100977636; called by muse, mutect2, varscan2
- GSK3A | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408231243, COSV99725127; called by muse, mutect2, varscan2
- GUSB | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs528899475, COSV59223945; called by muse, mutect2, varscan2
- H1-2 | c.636_638del p.K213del | In Frame Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs1198017017; called by pindel, varscan2
- HDX | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99946815; called by muse, mutect2, varscan2
- HECTD3 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs371750503, COSV99869967; called by muse, mutect2, varscan2
- HERC6 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99910472; called by muse, mutect2, varscan2
- HFE | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs897206619, COSV58513571; called by muse, mutect2
- HHIP | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760742577, COSV56841999; called by muse, mutect2, varscan2
- HIPK4 | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV99396456; called by muse, mutect2, varscan2
- HNF1A | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.187); catalogued as CM082856, COSV99982252; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646994; called by muse, mutect2, varscan2
- HOOK1 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.309); catalogued as COSV100969012; called by muse, mutect2, varscan2
- HOXA11 | c.895del p.I299Lfs*30 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs777829525; called by mutect2, varscan2
- HPS6 | c.1674del p.N559Mfs*54 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as rs764867254; called by mutect2, pindel, varscan2
- HSD11B2 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs749323350, COSV99340987; called by muse, mutect2, varscan2
- HTR4 | c.61G>C p.V21L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV100087427; called by muse, mutect2, varscan2
- HTRA2 | c.346del p.A116Qfs*93 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs779457274; called by mutect2, pindel
- HUWE1 | c.3163G>T p.A1055S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.644); catalogued as COSV99471047; called by muse, mutect2, varscan2
- ICE1 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99664056; called by muse, mutect2, varscan2
- IDH3G | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.468); catalogued as COSV99472995; called by muse, mutect2, varscan2
- IER5 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.583); catalogued as COSV100849671; called by muse, mutect2, varscan2
- IGF2R | c.6656A>T p.D2219V | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100807058; called by muse, mutect2
- IGHMBP2 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201054207, COSV54825451; ClinVar: uncertain significance; called by muse, mutect2
- IKBKE | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100898118; called by muse, mutect2, varscan2
- IL17RD | c.1639T>C p.C547R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.956); catalogued as COSV99576749; called by muse, mutect2, varscan2
- IL22RA2 | c.575dup p.N192Kfs*9 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | catalogued as rs756450081; called by mutect2, varscan2
- ILVBL | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99654643; called by muse, mutect2, varscan2
- ILVBL | c.1186+1G>A p.X396_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as rs1461283273, COSV99654645; called by muse, mutect2, varscan2
- INA | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); catalogued as COSV100878591; called by muse, mutect2, varscan2
- INHBA | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV99637308; called by muse, mutect2, varscan2
- INO80D | c.1540del p.M514Wfs*5 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as COSV68960008; called by mutect2, pindel, varscan2
- INPP4A | c.2702G>T p.R901L (on ENST00000074304 / NM_001134224.1; = p.R862L on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471383993, COSV50785371, COSV99302867; called by muse, mutect2, varscan2
- INPP4A | c.2797C>T p.R933C (on ENST00000074304 / NM_001134224.1; = p.R894C on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271977013, COSV50833571; called by muse, mutect2, varscan2
- INSYN2A | c.1295A>G p.Q432R | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV99727619; called by muse, mutect2, varscan2
- INSYN2A | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs538792856, COSV99727622; called by muse, mutect2, varscan2
- INTS14 | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.23); catalogued as COSV100499761; called by muse, mutect2, varscan2
- INTS5 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs774693364, COSV100399517; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IPCEF1 | c.1264del p.Q422Rfs*59 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs749464600; called by mutect2, pindel, varscan2
- IQCN | c.703del p.L235Wfs*17 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs748291022, COSV66574173; called by mutect2, pindel, varscan2
- IRAG1 | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV101350982; called by muse, mutect2, varscan2
- IRF2BP1 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV100138823; called by muse, mutect2
- IRF8 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV51900233; called by muse, mutect2
- ISOC2 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs916691073, COSV99321099; called by muse, varscan2
- ISOC2 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV99321101; called by muse, varscan2
- ITCH | c.1640A>G p.H547R (on ENST00000262650 / NM_001257137.3; = p.H506R on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99392129; called by muse, mutect2, varscan2
- ITGA2 | c.2840A>T p.N947I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV99670420; called by muse, mutect2, varscan2
- ITGA3 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV99143400; called by muse, mutect2, varscan2
- ITGA6 | c.3351del p.K1117Nfs*? (on ENST00000442250; = p.K1078Nfs*48 on NM_001079818.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs201055917; ClinVar: uncertain significance; called by mutect2, varscan2
- ITGA8 | c.2162C>T p.T721I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100958993; called by muse, mutect2
- ITGB1 | c.66A>G p.T22= | Splice Region (SNP) | VAF 4/29 reads (14%) | catalogued as COSV56486509; called by muse, mutect2, varscan2
- JARID2 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100521503, COSV59189684; called by muse, mutect2, varscan2
- JCAD | c.3373del p.Q1125Rfs*36 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | catalogued as rs886043177; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- KANSL1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs376632173; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KAT2B | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as rs1356338679, COSV99769014; called by muse, mutect2, varscan2
- KBTBD8 | c.1347A>T p.E449D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); catalogued as rs1559557613, COSV99805459; called by muse, mutect2, varscan2
- KCNA5 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1020769441, COSV99363713; ClinVar: uncertain significance; called by muse, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 26/46 reads (57%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNC2 | c.1780G>T p.G594* (on ENST00000549446 / NM_139137.4; = p.D594Y on NM_139136.3) | Nonsense Mutation (SNP) | VAF 36/95 reads (38%) | catalogued as COSV100128414; called by muse, mutect2, varscan2
- KCNC2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.435); catalogued as COSV100128417; called by muse, mutect2, varscan2
- KCNJ12 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561218777, COSV100054200; called by muse, mutect2, varscan2
- KCNJ13 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99289253; called by muse, mutect2
- KCNJ3 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99715397; called by muse, mutect2, varscan2
- KCTD8 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100759290; called by muse, mutect2, varscan2
- KDR | c.658+2T>C p.X220_splice | Splice Site (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99816947; called by muse, mutect2, varscan2
- KHDC4 | c.1546A>G p.R516G | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs749466397; called by muse, mutect2, varscan2
- KIAA1109 | c.9655C>T p.Q3219* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99147965; called by muse, mutect2, varscan2
- KIAA1549 | c.4009G>A p.A1337T | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.176); catalogued as COSV99650068; called by muse, mutect2
- KIAA1841 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as COSV99693448; called by muse, mutect2, varscan2
- KIDINS220 | c.4031G>A p.R1344H | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs1210384318; called by muse, mutect2
- KIF12 | c.1090C>T p.R364W (on ENST00000640217; = p.R226W on NM_138424.1) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375487574; called by muse, mutect2, varscan2
- KIF14 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs372557019, COSV100950670; called by muse, mutect2, varscan2
- KIF15 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100392614; called by muse, mutect2, varscan2
- KIR2DL4 | c.256G>A p.V86M (on ENST00000396284; = p.V47M on NM_001080770.2) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs768094760, COSV100610511; called by muse, mutect2, varscan2
- KLF9 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101009536; called by muse, mutect2
- KLHL24 | c.1106G>C p.G369A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99664779; called by muse, mutect2, varscan2
- KLK12 | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756042720, COSV99141828; called by muse, mutect2, varscan2
- KLK15 | c.406del p.E136Rfs*26 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs1457678928, COSV100032786, COSV56828407; called by mutect2, pindel, varscan2
- KMT2D | c.1480_1481insA p.L494Hfs*6 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | catalogued as COSV99978548; called by mutect2, pindel
- KNOP1 | c.1320del p.N441Tfs*21 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs752825616; called by mutect2, varscan2
- KPNA1 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60271089; called by muse, mutect2, varscan2
- KRT10 | c.813G>T p.M271I | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV99509950; called by muse, mutect2
- KRTAP10-5 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100552318; called by muse, mutect2
- KRTAP5-8 | c.341G>A p.C114Y | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs758646337, COSV101273117; called by muse, mutect2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMA2 | c.6986C>G p.T2329S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV101370233; called by muse, mutect2, varscan2
- LAMA5 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780029947, COSV53357888; called by muse, mutect2, varscan2
- LANCL3 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV101065515; called by muse, mutect2, varscan2
- LDB1 | c.1061G>T p.R354M (on ENST00000425280 / NM_001321612.2; = p.R320M on NM_003893.5) | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100756338; called by muse, mutect2, varscan2
- LDHAL6B | c.750G>T p.W250C | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99894787; called by muse, mutect2, varscan2
- LGALS4 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371360675; called by muse, mutect2, varscan2
- LIFR | c.2320A>G p.R774G | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as COSV99663562, COSV99664643; called by muse, mutect2, varscan2
- LILRA4 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV99392879, COSV99392966; called by muse, mutect2, varscan2
- LILRB1 | c.1664C>T p.A555V (on ENST00000427581; = p.A505V on NM_006669.6) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs763484018, COSV100207036; called by muse, mutect2, varscan2
- LRIF1 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); catalogued as rs777979628, COSV100870811; called by muse, mutect2, varscan2
- LRP1B | c.5160G>A p.M1720I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs752876097, COSV101253971; called by muse, mutect2, varscan2
- LRRC37A2 | c.4847_4849del p.E1616del | In Frame Del (DEL) | VAF 42/196 reads (21%) | catalogued as rs766913245; called by pindel, varscan2
- LRRC6 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99137806; called by muse, mutect2, varscan2
- LRRC8A | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758307862, COSV52187153; called by muse, mutect2, varscan2
- LYRM7 | c.18+2T>C p.X6_splice | Splice Site (SNP) | VAF 12/80 reads (15%) | catalogued as COSV101041558; called by muse, mutect2, varscan2
- LZTR1 | c.1910del p.P637Lfs*15 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | catalogued as rs780380199; called by mutect2, pindel, varscan2
- LZTS3 | c.1933G>A p.G645S (on ENST00000329152; = p.G599S on NM_001282533.2) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1391065205, COSV99417545; called by muse, mutect2, varscan2
- MAB21L1 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV100077680; called by muse, mutect2, varscan2
- MAB21L2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100461984; called by muse, mutect2, varscan2
- MAD2L1 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1041969104, COSV99633752; called by muse, mutect2
- MAGEC1 | c.1947G>T p.Q649H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV53579409, COSV99595089; called by muse, mutect2, varscan2
- MAGED2 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV99514425; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MAGEL2 | c.2989G>A p.A997T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs558186319, COSV100045801; called by muse, mutect2, varscan2
- MAP1LC3B | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs770128807, COSV99220730; called by muse, mutect2, varscan2
- MAP7D1 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs778875096, COSV100294287; called by muse, mutect2, varscan2
- MAP7D2 | c.1919C>A p.S640* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV101107223, COSV65529927; called by muse, mutect2, varscan2
- MARCHF3 | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.409); catalogued as COSV100427721; called by muse, mutect2, varscan2
- MARK1 | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs763095208, COSV100857102, COSV65068788; called by muse, mutect2
- MAST4 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs1405385344, COSV101282521; called by muse, mutect2, varscan2
- MBD3 | c.771C>A p.D257E | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.011); catalogued as rs755053188, COSV50083849, COSV99336893; called by muse, mutect2, varscan2
- MC5R | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs911107115, COSV61255052; called by muse, mutect2, varscan2
- MCC | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as rs1157838544, COSV100203060, COSV56734677; called by muse, mutect2, varscan2
- MCC | c.1500G>C p.K500N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV100202206; called by muse, mutect2
- MCCC1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99659471; called by muse, mutect2, varscan2
- MCF2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747639067, COSV58492945; called by muse, mutect2, varscan2
- MCF2L2 | c.1858del p.R620Afs*16 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as COSV100193332; called by mutect2, pindel, varscan2
- MCM7 | c.1380G>T p.E460D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100384774; called by muse, mutect2
- MCTP1 | c.2191G>T p.G731W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100386531; called by muse, mutect2, varscan2
- MDN1 | c.11812dup p.L3938Pfs*6 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs764349848; called by mutect2, pindel, varscan2
- MDN1 | c.9338C>T p.S3113L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs756074546, COSV65524504; called by muse, mutect2, varscan2
- MED12 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.953); catalogued as rs775072642, COSV100376700; ClinVar: benign; called by muse, mutect2, varscan2
- MED13 | c.6293C>T p.A2098V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101180838; called by muse, mutect2, varscan2
- MED13 | c.5076T>A p.C1692* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV101180839; called by muse, mutect2, varscan2
- MED24 | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.085); catalogued as rs532514222, COSV62418773; called by muse, mutect2, varscan2
- MEGF11 | c.701G>A p.C234Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99987108; called by muse, mutect2, varscan2
- MEGF8 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99234951; called by muse, mutect2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as rs745891632; called by mutect2, varscan2
- MIA2 | c.176del p.L59Cfs*22 | Frame Shift Del (DEL) | VAF 14/127 reads (11%) | catalogued as rs769553721, COSV54495286; called by mutect2, varscan2
- MLLT10 | c.2063G>T p.R688L (on ENST00000307729 / NM_001195626.3; = p.R704L on NM_004641.3) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV56997380, COSV57001896; called by muse, mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 15/48 reads (31%) | catalogued as rs777649506, COSV53202254; called by mutect2, pindel, varscan2
- MPO | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs757136407, COSV99832389; called by muse, mutect2, varscan2
- MRM3 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100444274; called by muse, mutect2, varscan2
- MRPL14 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751402548, COSV100921028; called by muse, mutect2, varscan2
- MRRF | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99938780; called by muse, mutect2, varscan2
- MS4A8 | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.35); catalogued as COSV100282414; called by muse, mutect2, varscan2
- MSRA | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); catalogued as rs1394307543, COSV100412543, COSV57813561; called by muse, mutect2, varscan2
- MTMR6 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV67809224; called by muse, mutect2
- MUC16 | c.21793G>A p.A7265T | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67471348; called by muse, mutect2, varscan2
- MUC16 | c.1112C>A p.A371D | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV101198710; called by muse, mutect2, varscan2
- MUC3A | c.9192G>A p.M3064I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100114162; called by muse, mutect2, varscan2
- MUC5B | c.7237C>A p.H2413N | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV101500101; called by muse, mutect2, varscan2
- MUC6 | c.7303G>A p.V2435M | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as rs758450273, COSV100172613; called by muse, mutect2, varscan2
- MYCBP2 | c.834G>A p.V278= (on ENST00000357337; = p.V316= on NM_015057.5) | Splice Region (SNP) | VAF 12/21 reads (57%) | catalogued as COSV100629439; called by muse, mutect2, varscan2
- MYG1 | c.556del p.E186Sfs*6 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as COSV99267014; called by mutect2, pindel, varscan2
- MYH1 | c.2101G>A p.G701S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs979734675, COSV56845460, COSV99875185; called by muse, mutect2, varscan2
- MYH14 | c.4014G>T p.Q1338H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99222093; called by muse, mutect2
- MYH3 | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as rs1215038260, COSV99877881; called by muse, mutect2
- MYH6 | c.3308C>T p.A1103V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.05); catalogued as COSV100676363; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO5B | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.753); catalogued as rs760481978, COSV99543937; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO5C | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99954275; called by muse, mutect2, varscan2
- MYO7A | c.4522C>T p.L1508F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV101289070; called by muse, mutect2, varscan2
- MYO9B | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as COSV101261400; called by muse, mutect2
- MYPOP | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100447821; called by muse, mutect2, varscan2
- MYT1 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60502941; called by muse, mutect2
- NAA35 | c.1700del p.K567Rfs*6 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs770577267; called by mutect2, varscan2
- NAGA | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV101124139; called by muse, mutect2
- NAPG | c.909G>T p.E303D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.978); catalogued as COSV100529686; called by muse, mutect2
- NASP | c.806G>A p.S269N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1420332684, COSV100601682; called by muse, mutect2, varscan2
- NAV3 | c.5119A>G p.S1707G | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs1172302363, COSV99888012; called by muse, mutect2
- NCOA2 | c.4382G>T p.R1461L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV51218268, COSV99144727; called by muse, mutect2, varscan2
- NDRG3 | c.826C>T p.R276C (on ENST00000349004 / NM_032013.4; = p.R264C on NM_022477.4) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1209865258, COSV100675327; called by muse, mutect2, varscan2
- NDST1 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as COSV99938701; called by muse, mutect2, varscan2
- NDST1 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99938702; called by muse, mutect2, varscan2
- NECTIN2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.358); catalogued as rs1415353897, COSV52979504, COSV99374822; called by muse, mutect2, varscan2
- NEFL | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV99647873; called by muse, mutect2, varscan2
- NEFM | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99647028; called by muse, mutect2, varscan2
- NEK5 | c.284A>C p.Q95P | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100839162; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NEURL1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs539510212, COSV100872816; called by muse, mutect2
- NFATC4 | c.2309G>A p.G770D | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); catalogued as COSV99144642; called by muse, mutect2, varscan2
- NFYC | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100438291; called by muse, mutect2
- NHS | c.4732G>A p.A1578T | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.307); catalogued as COSV101196451; called by muse, mutect2
- NINL | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs1486630257, COSV54010385; called by muse, mutect2
- NIPBL | c.6739C>T p.R2247C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1358086538, COSV99239435; called by muse, mutect2, varscan2
- NIPBL | c.6864G>T p.E2288D | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); catalogued as COSV99239441, COSV99239968; called by muse, mutect2, varscan2
- NKPD1 | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV99674752; called by muse, mutect2, varscan2
- NKX2-1 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as CM1310885, COSV100701803; called by muse, mutect2, varscan2
- NKX6-1 | c.1048A>G p.S350G | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs751750031, COSV99879977; called by muse, mutect2, varscan2
- NLRC5 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.475); catalogued as rs531478769, COSV99346693; called by muse, mutect2, varscan2
- NLRC5 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs778427595, COSV52663405, COSV52666012; called by muse, mutect2, varscan2
- NMNAT1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101020395; called by muse, mutect2, varscan2
- NOD1 | c.2365C>T p.L789F | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99767868; called by muse, mutect2, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOTCH4 | c.681G>T p.E227D | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV100900469; called by muse, mutect2
- NOVA1 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.273); catalogued as COSV99946787; called by muse, mutect2, varscan2
- NPAT | c.3185G>A p.R1062H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473195407, COSV53720981; called by muse, mutect2, varscan2
- NPR2 | c.1367T>C p.L456P | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs746462699, COSV100709356; called by muse, mutect2, varscan2
- NR1D2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56992767; called by muse, mutect2
- NR1H2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1568595480, COSV99516196; called by muse, mutect2, varscan2
- NR1H3 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389463548, COSV68008566; called by muse, mutect2, varscan2
- NR2C2 | c.1219T>G p.F407V (on ENST00000393102; = p.F426V on NM_003298.5) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100038339; called by muse, mutect2, varscan2
- NRDC | c.616dup p.T206Nfs*3 | Frame Shift Ins (INS) | VAF 18/58 reads (31%) | catalogued as rs747283256; called by mutect2, varscan2
- NRN1 | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV99784046; called by muse, mutect2, varscan2
- NUDT11 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101047017; called by muse, mutect2
- NUMA1 | c.4601C>T p.T1534I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as COSV100705908; called by muse, mutect2, varscan2
- NXN | c.542A>T p.N181I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV100402819; called by muse, mutect2, varscan2
- NXPE1 | c.693_694del p.C231* (on ENST00000424269; = p.C89* on NM_152315.5) | Nonsense Mutation (DEL) | VAF 20/52 reads (38%) | catalogued as rs1287150744; called by pindel, varscan2
- OBSCN | c.1493A>G p.Q498R | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99474789; called by muse, mutect2, varscan2
- OBSCN | c.1906C>A p.L636I | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV99474795; called by muse, mutect2, varscan2
- ODF2 | c.2165C>T p.A722V (on ENST00000434106 / NM_153433.2; = p.A698V on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs774318802, COSV100654470; called by muse, mutect2, varscan2
- OGDH | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99758463, COSV99758932; called by muse, mutect2, varscan2
- OLIG3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760047026, COSV62988529; called by muse, mutect2, varscan2
- OR10Q1 | c.275C>G p.A92G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100372172, COSV57470221; called by muse, mutect2, varscan2
- OR1L4 | c.633del p.F212Sfs*37 | Frame Shift Del (DEL) | VAF 64/275 reads (23%) | catalogued as COSV52339843; called by mutect2, pindel, varscan2
- OR5H1 | c.307del p.S103Rfs*6 | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | catalogued as rs774814732; called by mutect2, pindel, varscan2
- OR5H2 | c.209G>C p.S70T | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV100788665, COSV62351639; called by muse, mutect2, varscan2
- OR6C2 | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV100498661; called by muse, mutect2, varscan2
- OR6N1 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750291615, COSV100625103; called by muse, mutect2, varscan2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 33/76 reads (43%) | catalogued as rs751106039; called by mutect2, varscan2
- OSBPL5 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99720135; called by muse, mutect2, varscan2
- OSBPL8 | c.95G>C p.S32T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV99674671; called by muse, mutect2, varscan2
- OSGEPL1 | c.36del p.F12Lfs*12 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs750679212; called by mutect2, varscan2
- OVCA2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs944824870, COSV53983850; called by muse, mutect2, varscan2
- OXTR | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV100373076; called by muse, mutect2, varscan2
- P4HA1 | c.832del p.V278Lfs*23 | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | catalogued as rs1361469099; called by mutect2, pindel, varscan2
- PACSIN2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1379038128, COSV54316735; called by muse, mutect2, varscan2
- PADI3 | c.355_356del p.L119Gfs*7 | Frame Shift Del (DEL) | VAF 39/117 reads (33%) | catalogued as rs1490116104; called by pindel, varscan2
- PAK1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs937721392, COSV99583108; called by muse, mutect2, varscan2
- PANX2 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.026); catalogued as COSV99348060; called by muse, mutect2, varscan2
- PAQR9 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100503722; called by muse, mutect2, varscan2
- PARD3B | c.2567G>A p.R856H (on ENST00000406610 / NM_001302769.2; = p.R787H on NM_057177.7) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as rs202062600, COSV100592522; called by muse, mutect2, varscan2
- PAX6 | c.1124dup p.H376Tfs*36 | Frame Shift Ins (INS) | VAF 19/52 reads (37%) | catalogued as rs756801119; called by mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 26/39 reads (67%) | catalogued as rs753190856; called by mutect2, varscan2
- PCDH10 | c.360del p.S121Lfs*7 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs759095467; called by mutect2, pindel, varscan2
- PCDHA2 | c.2363T>G p.L788R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV100973689; called by muse, mutect2, varscan2
- PCDHA6 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782678285, COSV65353351; called by muse, mutect2, varscan2
- PCDHA9 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV65323887; called by muse, mutect2
- PCDHB2 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.415); catalogued as COSV99522921; called by muse, mutect2, varscan2
- PCDHGA12 | c.2773_2775del p.K925del | In Frame Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs1427934561; called by pindel, varscan2
- PCNT | c.6410del p.G2137Vfs*2 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as COSV64032914; called by mutect2, pindel, varscan2
- PCNX1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs759133289, COSV53102195; called by muse, varscan2
- PDCD6IP | c.602del p.L201* | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs781474699; called by mutect2, varscan2
- PDCD6IP | c.2422G>T p.G808* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100218587; called by muse, mutect2, varscan2
- PDE8A | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as rs200830973, COSV100051644; called by muse, mutect2, varscan2
- PDXK | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs200647993, COSV52366093; called by muse, mutect2, varscan2
- PEG3 | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99687805; called by muse, mutect2, varscan2
- PER1 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs771601418, COSV57918527; called by muse, mutect2, varscan2
- PFDN6 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763752325, COSV101004730; called by muse, mutect2, varscan2
- PHETA2 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs745955390, COSV100408887; called by muse, mutect2, varscan2
- PHF10 | c.1448dup p.T484Nfs*18 | Frame Shift Ins (INS) | VAF 8/23 reads (35%) | catalogued as rs754137375; called by mutect2, varscan2
- PHLDB1 | c.2986G>A p.V996M | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs782253532, COSV100616348; called by muse, mutect2, varscan2
- PHLDB2 | c.2451del p.V822Lfs*6 (on ENST00000393925 / NM_001134439.2; = p.V779Lfs*6 on NM_145753.2) | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | catalogued as rs1193567996, COSV101208463; called by mutect2, pindel, varscan2
- PHLPP1 | c.2711A>G p.N904S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99407618; called by muse, mutect2, varscan2
- PIANP | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.155); catalogued as COSV100272291; called by muse, mutect2, varscan2
- PIK3R1 | c.1123G>T p.G375W (on ENST00000521381 / NM_181523.3; = p.G105W on NM_181504.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104387194, COSV99141246; called by muse, mutect2, varscan2
- PIK3R1 | c.1566A>C p.Q522H (on ENST00000521381 / NM_181523.3; = p.Q252H on NM_181504.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV57135901, COSV99141254; called by muse, mutect2, varscan2
- PIM3 | c.909C>A p.S303R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.168); catalogued as COSV100638395; called by muse, mutect2, varscan2
- PKD1 | c.9881C>T p.A3294V | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99237425; called by muse, mutect2, varscan2
- PKP2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200095747, COSV50742302; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLA2G4A | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV100820436; called by muse, mutect2, varscan2
- PLA2G4D | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs528090274, COSV99076346; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs745860467; called by mutect2, varscan2
- PLEKHM2 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV101009061; called by muse, mutect2, varscan2
- PLIN5 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200649823, COSV101113440; called by muse, mutect2, varscan2
- PLXNA3 | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63753534; called by muse, mutect2, varscan2
- POC1B | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100544091; called by muse, mutect2, varscan2
- POLG | c.3140G>T p.R1047L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as CM030940, COSV99174565; called by muse, mutect2, varscan2
- POLR3C | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100492806; called by muse, mutect2, varscan2
- PON2 | c.195del p.F65Lfs*5 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | catalogued as rs1201102139; called by mutect2, pindel, varscan2
- PPIL1 | c.17del p.P6Qfs*56 | Frame Shift Del (DEL) | VAF 38/97 reads (39%) | catalogued as COSV63836906; called by mutect2, varscan2
- PPL | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.473); catalogued as COSV100630574; called by muse, mutect2, varscan2
- PPP1CC | c.941G>T p.R314M | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as COSV100534802; called by muse, mutect2, varscan2
- PPP1R10 | c.2084del p.G695Vfs*222 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as rs760405117; called by mutect2, pindel, varscan2
- PPP1R11 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs770307762, COSV99748194; called by muse, mutect2, varscan2
- PPP4R3B | c.2435C>T p.T812M (on ENST00000616407 / NM_001122964.3; = p.T727M on NM_020463.4) | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs777033104, COSV99701537; called by muse, mutect2, varscan2
- PRDM2 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52454190; called by muse, mutect2, varscan2
- PRKAR1B | c.260del p.P87Rfs*5 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs764069617; called by mutect2, pindel, varscan2
- PRKCSH | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52954296, COSV99371338; called by muse, mutect2, varscan2
- PRPF19 | c.584C>A p.P195H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99920488; called by muse, mutect2, varscan2
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PSAT1 | c.1079T>C p.F360S (on ENST00000376588 / NM_058179.4; = p.F314S on NM_021154.5) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV100716521; called by muse, mutect2, varscan2
- PSEN2 | c.299T>A p.I100N | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100422904; called by muse, mutect2, varscan2
- PSMA8 | c.150del p.K50Nfs*12 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs749240094; called by mutect2, varscan2
- PTCD2 | c.570G>C p.E190D | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV100348810; called by muse, mutect2, varscan2
- PTGER4 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100201461; called by muse, mutect2, varscan2
- PTPN6 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as rs782761798, COSV100016975; called by muse, mutect2, varscan2
- PTPRD | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100643846; called by muse, mutect2, varscan2
- PTPRU | c.3574G>A p.V1192M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs748129270, COSV100112013; called by muse, mutect2, varscan2
- PWWP3B | c.685G>C p.A229P | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV100531032, COSV61801625; called by muse, mutect2, varscan2
- PXK | c.1375del p.R459Efs*4 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs751548577; called by mutect2, varscan2
- PXK | c.1466-1G>A p.X489_splice | Splice Site (SNP) | VAF 40/92 reads (43%) | catalogued as COSV100243948; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV100365194; called by muse, mutect2, varscan2
- RAB13 | c.247-2A>C p.X83_splice | Splice Site (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100885219; called by muse, mutect2, varscan2
- RAB14 | c.105del p.K35Nfs*18 | Frame Shift Del (DEL) | VAF 18/36 reads (50%) | catalogued as rs1564320972; called by mutect2, varscan2
- RAB37 | c.668T>G p.M223R (on ENST00000392613 / NM_001006638.3; = p.M216R on NM_175738.5) | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV99379883; called by muse, mutect2
- RAB39A | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV100269122, COSV57695711; called by muse, mutect2, varscan2
- RAD54L2 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs369391503; called by muse, mutect2, varscan2
- RADIL | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs371257914; called by muse, varscan2
- RALB | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99732473; called by muse, mutect2, varscan2
- RALGAPA1 | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs771666236, COSV51882169; called by muse, mutect2, varscan2
- RAPGEF2 | c.3259del p.I1087Ffs*98 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as rs760669443; called by mutect2, pindel*, varscan2
- RAPGEF6 | c.1918del p.S640Vfs*59 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as rs752725730; called by mutect2, varscan2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
- RASAL3 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs746119444, COSV99652793; called by muse, mutect2, varscan2
- RBKS | c.924G>C p.Q308H | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as rs888816409, COSV99941368; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as rs762006287; called by mutect2, varscan2
- RELB | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV99672786; called by muse, mutect2, varscan2
- RFX1 | c.1869G>T p.M623I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs766107840, COSV99585876; called by muse, mutect2, varscan2
- RGL2 | c.608del p.G203Afs*49 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs762949421; called by mutect2, varscan2
- RGPD1 | c.1282C>T p.H428Y (on ENST00000409776; = p.H436Y on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV101233585; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS3 | c.1343G>A p.R448H (on ENST00000350696 / NM_001282923.2; = p.R336H on NM_017790.4) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs773984530, COSV58283671, COSV58283795; called by muse, varscan2
- RHBDF2 | c.932dup p.L312Tfs*52 | Frame Shift Ins (INS) | VAF 15/58 reads (26%) | catalogued as rs756639910; called by mutect2, varscan2
- RIF1 | c.1414del p.S472Pfs*34 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as COSV54616696; called by mutect2, varscan2
- RIMS2 | c.1532C>T p.S511L (on ENST00000666250 / NM_001348490.2; = p.S319L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51650842; called by muse, mutect2, varscan2
- RIT1 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100851159; called by muse, mutect2
- RNF112 | c.1192dup p.Q398Pfs*4 | Frame Shift Ins (INS) | VAF 21/62 reads (34%) | catalogued as rs779219461; called by mutect2, pindel, varscan2
- RNF145 | c.339G>A p.M113I (on ENST00000424310 / NM_001199383.2; = p.M141I on NM_144726.2) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1162248022, COSV99193312; called by muse, mutect2, varscan2
- RNF6 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs1162440085, COSV100644593; called by muse, mutect2, varscan2
- RNLS | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100076328; called by muse, mutect2, varscan2
- RP1L1 | c.5684C>T p.A1895V | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV101223033; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRAS | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV99881987; called by muse, mutect2, varscan2
- RSPO2 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV99409172; called by muse, mutect2, varscan2
- RXYLT1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99706757; called by muse, mutect2, varscan2
- SALL1 | c.3316A>C p.S1106R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.094); catalogued as COSV99171811; called by muse, mutect2
- SALL3 | c.3049A>G p.M1017V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs201364430; called by muse, mutect2, varscan2
- SAMD11 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV100497886; called by muse, mutect2, varscan2
- SAMD15 | c.1781A>G p.D594G | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV99374816; called by muse, mutect2, varscan2
- SAMSN1 | c.561G>A p.K187= | Splice Region (SNP) | VAF 19/52 reads (37%) | catalogued as COSV99580940; called by muse, mutect2, varscan2
- SASH1 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs768183967, COSV100820990; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs765867975; called by mutect2, varscan2
- SCN4A | c.2500G>A p.G834S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs899627353, COSV71127545; called by muse, mutect2, varscan2
- SDE2 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs979841467, COSV55251965; called by muse, mutect2, varscan2
- SDF4 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs547040308, COSV55417366, COSV55420930; called by muse, mutect2, varscan2
- SEC16A | c.3187C>T p.P1063S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.476); catalogued as COSV99256750; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 22/41 reads (54%) | catalogued as rs750651342; called by mutect2, varscan2
- SERPINF1 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV54615207; called by muse, mutect2, varscan2
- SERTAD4 | c.892A>G p.S298G | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100882594; called by muse, mutect2, varscan2
- SF1 | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as COSV99918034; called by muse, mutect2, varscan2
- SF3A1 | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV99305270; called by muse, mutect2, varscan2
- SGIP1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1458787403, COSV52763471; called by muse, mutect2
- SGK1 | c.514_515insA p.L172Yfs*9 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as COSV99397862; called by mutect2, pindel, varscan2
- SH2D7 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs752838158, COSV60926778; called by muse, mutect2, varscan2
- SH3BP2 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1295990769, COSV100696884; called by muse, mutect2, varscan2
- SH3GLB1 | c.911G>A p.C304Y | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100990747; called by muse, mutect2, varscan2
- SH3RF1 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99498783; called by muse, mutect2, varscan2
- SH3RF2 | c.1804A>G p.M602V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100767635; called by muse, mutect2, varscan2
- SH3RF3 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs753317886, COSV58685651, COSV58688989; called by muse, mutect2, varscan2
- SH3TC2 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.598); catalogued as rs1465198831, COSV100101372; ClinVar: uncertain significance; called by muse, mutect2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs1469942319; called by mutect2, varscan2
- SHROOM2 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1209932248, COSV101098280; called by muse, mutect2, varscan2
- SHROOM2 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as rs756799909, COSV66605262; called by muse, mutect2, varscan2
- SIGLEC10 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as rs755613587, COSV59480577; called by muse, mutect2, varscan2
- SIL1 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.056); catalogued as rs1050490804, COSV99497831; called by muse, mutect2, varscan2
- SIX6 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as rs1478357698, COSV59801804; called by muse, mutect2, varscan2
- SLC11A2 | c.1480C>T p.P494S (on ENST00000394904 / NM_001379455.1; = p.P465S on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as rs971396877, COSV100014536; called by muse, mutect2
- SLC18A2 | c.1414A>G p.S472G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV100041424; called by muse, mutect2, varscan2
- SLC19A1 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100229162; called by muse, mutect2, varscan2
- SLC1A1 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.092); catalogued as COSV99261211; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs749849908; called by mutect2, varscan2
- SLC25A46 | c.717T>G p.C239W | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100582531; called by muse, mutect2, varscan2
- SLC30A6 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV99249447; called by muse, mutect2, varscan2
- SLC32A1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV99461921; called by muse, mutect2
- SLC40A1 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.581); catalogued as COSV99656181; called by muse, mutect2, varscan2
- SLC46A3 | c.158dup p.N53Kfs*21 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | catalogued as rs748831793; called by mutect2, varscan2
- SLC6A18 | c.1535C>A p.P512H | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99722076; called by muse, mutect2, varscan2
- SLC6A7 | c.1316T>C p.L439P | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100046045; called by muse, mutect2, varscan2
- SLC9B1 | c.909dup p.V304Cfs*7 | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | catalogued as rs769618988; called by mutect2, pindel, varscan2
- SLFNL1 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs368949883; called by muse, mutect2, varscan2
- SMAD2 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1226662382, COSV50992817; called by muse, mutect2
- SMC3 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.42); catalogued as COSV100699831; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 41/61 reads (67%) | catalogued as rs747405143; called by mutect2, pindel, varscan2
- SMURF2 | c.1430C>A p.P477Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52317647, COSV99300451; called by muse, mutect2, varscan2
- SON | c.4849G>A p.A1617T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs768017475, COSV51659695; called by muse, mutect2, varscan2
- SOS2 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV99365566; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | catalogued as rs746109620; called by mutect2, varscan2
- SPAG5 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100410490; called by muse, mutect2, varscan2
- SPECC1 | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99821417; called by muse, mutect2
- SPEG | c.2800C>T p.R934C | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs34398769, COSV100403481; called by muse, mutect2, varscan2
- SPRED2 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710113; called by muse, mutect2, varscan2
- SPTAN1 | c.1927C>T p.H643Y | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV100823330, COSV63987541; called by muse, mutect2, varscan2
- SPTBN4 | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100150257; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as rs748467821; called by mutect2, varscan2
- SRCAP | c.9135G>T p.Q3045H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.188); catalogued as COSV99349557; called by muse, mutect2, varscan2
- SRRT | c.2003A>G p.E668G | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.922); catalogued as COSV99573850; called by muse, mutect2, varscan2
- STARD4 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.18); catalogued as rs566737403, COSV99685247; called by muse, mutect2, varscan2
- STK3 | c.1450A>G p.K484E | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101372465; called by muse, mutect2, varscan2
- STON2 | c.1586G>C p.R529P (on ENST00000649389 / NM_001366849.2; = p.R472P on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99964488; called by muse, mutect2, varscan2
- STRIP2 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.695); catalogued as rs904822742, COSV99973555; called by muse, mutect2
- STX17 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99407890; called by muse, mutect2, varscan2
- SUFU | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100882911; called by muse, mutect2, varscan2
- SVIL | c.5807A>G p.E1936G (on ENST00000355867 / NM_021738.3; = p.E1510G on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100881065; called by muse, mutect2, varscan2
- SWAP70 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs753046053, COSV100013594; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 18/33 reads (55%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNCRIP | c.1289A>G p.D430G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV100784056; called by muse, mutect2, varscan2
- SYNRG | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as rs753877348; called by muse, mutect2, varscan2
- TAAR1 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770968548, COSV99257498; called by muse, mutect2, varscan2
- TAF1L | c.4183C>T p.R1395* | Nonsense Mutation (SNP) | VAF 63/136 reads (46%) | catalogued as rs1241463990, COSV54260200; called by muse, mutect2, varscan2
- TANC2 | c.5143C>T p.P1715S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.24); catalogued as rs1180989630, COSV101267285; called by muse, mutect2
- TANK | c.1234del p.D412Ifs*27 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | catalogued as COSV52043878; called by mutect2, pindel, varscan2
- TASP1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs201419798, COSV61812590; called by muse, mutect2, varscan2
- TBC1D17 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs912616149, COSV99680486; called by muse, mutect2, varscan2
- TBC1D24 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.394); catalogued as rs370614433; called by muse, mutect2, varscan2
- TBC1D9B | c.334A>G p.K112E | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100783456; called by muse, varscan2
- TBCE | c.1150+2T>C p.X384_splice (on ENST00000366601; = p.X447_splice on NM_003193.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100782993; called by muse, mutect2, varscan2
- TBXA2R | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.426); catalogued as COSV100916151, COSV100916348; called by muse, mutect2
- TCF25 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs1178194741, COSV99642473, COSV99642694; called by muse, mutect2, varscan2
- TCP11L2 | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100135234, COSV54432334; called by muse, mutect2, varscan2
- TCTN1 | c.935T>C p.V312A (on ENST00000551590 / NM_001173975.3; = p.V298A on NM_024549.6) | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100885897; called by muse, mutect2, varscan2
- TDRD1 | c.1984A>G p.S662G | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV99314229; called by muse, mutect2
- TDRD3 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs140911407; called by muse, mutect2, varscan2
- TENM2 | c.6112G>A p.V2038I (on ENST00000518659 / NM_001122679.2; = p.V1799I on NM_001080428.3) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as rs374139941; called by muse, mutect2, varscan2
- TENT4A | c.1130T>G p.L377R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100048724; called by muse, mutect2, varscan2
- TEX14 | c.2450G>A p.S817N (on ENST00000240361 / NM_001201457.2; = p.S811N on NM_031272.5) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV99541689; called by muse, mutect2
- TEX264 | c.620A>T p.E207V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV100392522; called by muse, mutect2, varscan2
- TEX29 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV52094326; called by muse, mutect2, varscan2
- TFDP1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs750579074, COSV100945760; called by muse, mutect2, varscan2
- TFR2 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs750378395, COSV99774389; called by muse, mutect2, varscan2
- TG | c.5140G>T p.G1714* | Nonsense Mutation (SNP) | VAF 26/94 reads (28%) | catalogued as COSV99599576; called by muse, mutect2, varscan2
- TGFBI | c.566T>C p.M189T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100526343; called by muse, mutect2, varscan2
- THBS2 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV100827708; called by muse, mutect2, varscan2
- THNSL1 | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100896140; called by muse, mutect2, varscan2
- TIMP4 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55138795, COSV99825950; called by muse, mutect2, varscan2
- TIPARP | c.832T>C p.W278R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99903719; called by muse, mutect2, varscan2
- TLCD5 | c.89G>A p.R30Q (on ENST00000375095 / NM_001198671.2; = p.R52Q on NM_174926.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as rs1215758984, COSV100080953; called by muse, mutect2, varscan2
- TLE3 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); catalogued as COSV100450114; called by muse, mutect2, varscan2
- TM4SF18 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs777428789, COSV56058582; called by muse, mutect2, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | catalogued as rs760930120; called by mutect2, varscan2
- TM9SF4 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54110378; called by muse, mutect2, varscan2
- TMEM213 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV100022793; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 36/72 reads (50%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM62 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as rs768629081, COSV53042185; called by muse, mutect2, varscan2
- TMEM63C | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs780100397, COSV100029265; called by muse, mutect2, varscan2
- TMUB2 | c.349C>T p.R117W (on ENST00000538716 / NM_001353177.2; = p.R97W on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs764517813, COSV100116069; called by mutect2, varscan2
- TNFAIP2 | c.1528C>T p.Q510* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100280851; called by muse, mutect2, varscan2
- TNFAIP3 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99396446; called by muse, mutect2, varscan2
- TNFRSF19 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99947181; called by muse, mutect2, varscan2
- TNFSF9 | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99832331; called by mutect2, varscan2
- TNRC6B | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV57294459; called by muse, mutect2, varscan2
- TNS1 | c.4445C>T p.P1482L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762766252, COSV99410084; called by muse, mutect2, varscan2
- TNXB | c.8552C>T p.A2851V (on ENST00000647633; = p.A2604V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.644); catalogued as COSV64472631; called by muse, mutect2
- TPP2 | c.2030T>C p.V677A | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV101060201; called by muse, mutect2, varscan2
- TRDN | c.1050del p.E351Sfs*13 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs753514580; called by mutect2, varscan2
593 further variants in this file (275 protein-altering or splice-affecting, 277 silent, 41 other) are not listed here.
